Somatic mutation profile of tumor specimen HCM-BROD-0012-C71-86A (aliquot HCM-BROD-0012-C71-86A-01D-A78L-36) from HCMI case HCM-BROD-0012-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,744 days).
Specimen HCM-BROD-0012-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a7507c-5997-4022-b1a9-783c985b583d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0012-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0012-C71-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e68c03f-5800-4231-b71f-77c28e066242

The open-access MAF lists 77 somatic variants for this specimen: 47 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Splice Site 5, Intron 4, RNA 3, Nonsense Mutation 2, 5'UTR 2, 3'UTR 2, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7A | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 155/336 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs797045344, CM109533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLA | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 110/215 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs104894827, CM890057; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 153/291 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918459, CM013416, COSV61007856; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL645922.1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 287/570 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs753059312, COSV54960912; called by muse, mutect2, varscan2
- ALG5 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99523601; called by muse, mutect2, varscan2
- ARSF | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 160/380 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201726785; called by muse, mutect2, varscan2
- CBY2 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60119502; called by muse, mutect2, varscan2
- CNTNAP5 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1207750958, COSV70472432, COSV70483251; called by muse, mutect2, varscan2
- EXOC3L1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139069832; called by muse, mutect2, varscan2
- FAM186A | c.580del p.I194Yfs*16 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | catalogued as rs1260976214; called by mutect2, pindel, varscan2
- ISG20 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs549880749, COSV60143590; called by muse, mutect2, varscan2
- KANK4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs759887895; called by muse, mutect2, varscan2
- KCNH3 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 169/320 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs763321479, COSV57793215; called by muse, mutect2, varscan2
- MAGEB6 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs770333290, COSV100983635, COSV66873231; called by muse, mutect2, varscan2
- NF2 | c.1341-2A>C p.X447_splice | Splice Site (SNP) | VAF 236/487 reads (48%) | catalogued as CS115647, COSV58527036; called by muse, mutect2, varscan2
- NRP1 | c.624C>A p.Y208* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV55178496; called by muse, mutect2
- OR2L8 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61727901; called by muse, mutect2
- PCDH15 | c.4212-2A>C p.X1404_splice | Splice Site (SNP) | VAF 128/261 reads (49%) | catalogued as COSV57412888; called by muse, varscan2
- PRKX | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 40/663 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs751945456; called by muse, mutect2
- SCN5A | c.4226A>T p.Y1409F (on ENST00000333535 / NM_198056.3; = p.Y1408F on NM_000335.5) | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as CM100717; called by muse, mutect2
- SLCO4C1 | c.1844T>C p.L615S | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1416876929; called by muse, mutect2, varscan2
- STARD6 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100323564; called by muse, varscan2
- TNIP2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 120/223 reads (54%) | catalogued as rs556774838; called by muse, mutect2, varscan2
- TPTE2 | c.593A>G p.E198G (on ENST00000400230 / NM_199254.2; = p.E121G on NM_130785.3) | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as rs1305168994; called by muse, mutect2, varscan2
- ZNF234 | c.1169A>G p.H390R | Missense Mutation (SNP) | VAF 149/331 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753238363, COSV70604230; called by muse, mutect2, varscan2
- ZNF536 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as rs755613678, COSV100835485, COSV100835753; called by muse, mutect2, varscan2
- ACTL7A | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2
- BOK | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENOX2 | c.340+1_340+2del p.X114_splice (on ENST00000338144 / NM_001382520.1; = p.X85_splice on NM_006375.3 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 47/109 reads (43%) | called by mutect2, pindel, varscan2
- FAM205A | c.3273G>C p.K1091N | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2
- GLUD1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 145/293 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GNAL | c.547-1G>A p.X183_splice (on ENST00000269162 / NM_001142339.3; = p.X260_splice on NM_182978.4) | Splice Site (SNP) | VAF 83/187 reads (44%) | called by muse, mutect2, varscan2
- HOXA10 | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 196/461 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KATNAL1 | c.1013-1G>A p.X338_splice | Splice Site (SNP) | VAF 60/109 reads (55%) | called by muse, mutect2, varscan2
- KCTD8 | c.902T>C p.F301S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- LCMT1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRTM2 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LUC7L2 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYH4 | c.4389G>T p.K1463N | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPIPB15 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 303/1090 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); called by muse, varscan2
- PSMC5 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- QKI | c.325dup p.T109Nfs*6 | Frame Shift Ins (INS) | VAF 68/93 reads (73%) | called by mutect2, pindel, varscan2
- RAB40AL | c.454T>G p.F152V | Missense Mutation (SNP) | VAF 213/487 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RPIA | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 87/159 reads (55%) | SIFT tolerated (0.56); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SHROOM4 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 181/363 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TIMM29 | c.388T>A p.C130S | Missense Mutation (SNP) | VAF 193/381 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- USP14 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ABCA1 | c.1320G>A p.L440= | Silent (SNP) | VAF 290/290 reads (100%) | called by muse, mutect2, varscan2
- ANKRD10 | c.138C>A p.P46= | Silent (SNP) | VAF 26/375 reads (7%) | called by muse, mutect2
- CLEC17A | c.714G>A p.Q238= | Silent (SNP) | VAF 89/195 reads (46%) | called by muse, mutect2, varscan2
- DOC2B | c.471C>T p.D157= | Silent (SNP) | VAF 67/146 reads (46%) | called by muse, mutect2, varscan2
- EFCC1 | c.315C>T p.S105= | Silent (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- GUF1 | c.99G>A p.A33= | Silent (SNP) | VAF 125/255 reads (49%) | catalogued as COSV55785447; called by muse, mutect2, varscan2
- ITGA11 | c.3084C>T p.D1028= | Silent (SNP) | VAF 94/194 reads (48%) | catalogued as rs61729773; called by muse, mutect2, varscan2
- KCNB2 | c.1524C>T p.F508= | Silent (SNP) | VAF 103/237 reads (43%) | catalogued as rs752821146, COSV73049012; called by muse, mutect2, varscan2
- MCF2L | c.3087C>T p.D1029= (on ENST00000375608; = p.D997= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs781264646, COSV56181082; called by muse, mutect2, varscan2
- MEX3D | c.1212C>T p.A404= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs1415261817; called by muse, mutect2, varscan2
- MRI1 | c.1056C>T p.A352= (on ENST00000040663 / NM_001031727.4; = p.A305= on NM_032285.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/135 reads (38%) | called by muse, mutect2, varscan2
- MUC5B | c.12654C>A p.I4218= | Silent (SNP) | VAF 42/454 reads (9%) | called by muse, mutect2, varscan2
- NOTCH3 | c.3222G>A p.E1074= | Silent (SNP) | VAF 176/469 reads (38%) | called by muse, mutect2, varscan2
- OR51F1 | c.576T>C p.D192= | Silent (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- OR5M8 | c.111G>A p.T37= | Silent (SNP) | VAF 78/198 reads (39%) | catalogued as rs376992051; called by muse, mutect2, varscan2
- PTPRB | c.5454G>A p.A1818= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs369428514; called by muse, mutect2, varscan2
- TANC1 | c.5154C>T p.P1718= | Silent (SNP) | VAF 141/293 reads (48%) | catalogued as COSV55096794; called by muse, mutect2, varscan2
- UPF1 | c.1764G>A p.L588= (on ENST00000599848 / NM_001297549.2; = p.L577= on NM_002911.4) | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as COSV53198280; called by muse, mutect2, varscan2
- ACSF3 | c.*1242C>T | 3'UTR (SNP) | VAF 136/268 reads (51%) | called by muse, mutect2, varscan2
- CCDC74A | c.250+190G>A | Intron (SNP) | VAF 152/312 reads (49%) | called by muse, mutect2, varscan2
- CTDP1 | chr18:79679572 G>T | 5'Flank (SNP) | VAF 29/400 reads (7%) | called by muse, mutect2
- EPB41 | c.1845+36T>G | Intron (SNP) | VAF 96/248 reads (39%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1899-18G>A | Intron (SNP) | VAF 143/276 reads (52%) | called by muse, mutect2, varscan2
- GVINP1 | n.4279G>C | RNA (SNP) | VAF 100/196 reads (51%) | called by muse, mutect2, varscan2
- H2AZ2 | c.*15C>T | 3'UTR (SNP) | VAF 73/139 reads (53%) | called by muse, varscan2
- MMP26 | c.-145+92644T>A | Intron (SNP) | VAF 111/214 reads (52%) | called by muse, mutect2, varscan2
- PPIL6 | c.-9G>A | 5'UTR (SNP) | VAF 21/21 reads (100%) | called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.-18C>T | 5'UTR (SNP) | VAF 87/111 reads (78%) | called by muse, mutect2, varscan2
- XIST | n.10941T>A | RNA (SNP) | VAF 68/133 reads (51%) | called by muse, mutect2, varscan2
- XIST | n.7432_7433del | RNA (DEL) | VAF 71/215 reads (33%) | catalogued as rs1047292168; called by mutect2, pindel, varscan2
